TARGET case TARGET-20-PACEGD — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/0fe29a81-74fc-5158-ae13-0437bc272805

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Dead; Days to death: 334 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 1.9 years (691 days); Year of diagnosis: 1998; Days to last follow up: 334 days.

Biospecimens (1 sample)
- Sample TARGET-20-PACEGD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
